Somatic mutation profile of tumor specimen TCGA-34-5240-01A (aliquot TCGA-34-5240-01A-01D-1441-08) from TCGA case TCGA-34-5240, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.2 years (26,735 days).
Specimen TCGA-34-5240-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7603c50b-f17f-422b-b46b-3562d810d35f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5240-10A (Blood Derived Normal), aliquot TCGA-34-5240-10A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67febf49-d292-43ad-9b0c-e2482018239e

The open-access MAF lists 187 somatic variants for this specimen: 130 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 52, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 4, RNA 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 17/45 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 41/77 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.380+2T>G p.X127_splice | Splice Site (SNP) | VAF 50/77 reads (65%) | hotspot (GDC flag); catalogued as CS158869, COSV57300593, COSV57301520, COSV57310513; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 39/67 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.2669G>T p.G890V | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63971610, COSV63973718; called by muse, mutect2, varscan2
- ADGRD1 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55441948, COSV55449677; called by muse, mutect2, varscan2
- AGTRAP | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58668630; called by muse, mutect2, varscan2
- ASTN2 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as COSV57765221; called by muse, mutect2, varscan2
- ATXN3L | c.967A>G p.S323G | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV66075493; called by muse, mutect2
- BACE2 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 195/497 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV57738516; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as rs759875052, COSV63244234, COSV63245200; called by muse, mutect2, varscan2
- CCDC105 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52963596; called by muse, mutect2, varscan2
- CCDC136 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs368845976; called by muse, mutect2
- CCNB3 | c.2063C>A p.S688Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV52071656; called by muse, mutect2, varscan2
- CD1E | c.1089G>C p.Q363H | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV63770523; called by muse, mutect2, varscan2
- CDH10 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 142/361 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs759342297, COSV52575960; called by muse, mutect2, varscan2
- CDH15 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs186344601, COSV57027977; called by muse, varscan2
- CDH8 | c.1899del p.L633Ffs*3 | Frame Shift Del (DEL) | VAF 46/88 reads (52%) | catalogued as COSV54884322; called by mutect2, pindel, varscan2
- CHRNA1 | c.430G>A p.D144N (on ENST00000261007 / NM_001039523.3; = p.D119N on NM_000079.4) | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.964); catalogued as COSV53682354; called by muse, mutect2, varscan2
- CLCN4 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 23/159 reads (14%) | catalogued as COSV66465852; called by muse, mutect2, varscan2
- CLEC4D | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1323448065, COSV55228556; called by muse, mutect2, varscan2
- COL5A3 | c.3181G>A p.G1061R | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53408528; called by muse, mutect2, varscan2
- CXCR3 | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65461733; called by muse, mutect2, varscan2
- CYP4B1 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867178708, COSV54722595; called by muse, mutect2
- DACH2 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1368471132, COSV64162065; called by muse, mutect2, varscan2
- DACH2 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1569485014, COSV64165186; called by muse, mutect2, varscan2
- DCAF4L2 | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 66/105 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV60477527; called by muse, mutect2, varscan2
- DGKI | c.2094G>T p.Q698H | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55943541; called by muse, mutect2, varscan2
- DGKI | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55943562; called by muse, mutect2, varscan2
- DNAH11 | c.2840A>T p.Q947L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV60948533; called by muse, mutect2, varscan2
- EDEM3 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58923236; called by muse, mutect2
- ETFA | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 51/100 reads (51%) | catalogued as rs1047426224, COSV51211328, COSV51211783; called by muse, mutect2, varscan2
- EXTL1 | c.1244C>A p.P415H | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65337292; called by muse, mutect2, varscan2
- F13B | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs770302077, COSV66373070, COSV66373128; called by muse, mutect2
- F5 | c.6001C>A p.Q2001K | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1445925417, COSV63122413; called by muse, mutect2, varscan2
- FAT1 | c.11338T>A p.C3780S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71673191; called by muse, mutect2, varscan2
- FBN2 | c.1244G>A p.R415K | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV52503948, COSV99326521; called by muse, mutect2, varscan2
- FHL1 | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 150/307 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV61780322; called by muse, mutect2, varscan2
- FSHR | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.17); catalogued as COSV100436480, COSV58620693; called by muse, mutect2, varscan2
- GPC3 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 50/245 reads (20%) | catalogued as COSV63661560; called by muse, mutect2, varscan2
- GPR82 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.385); catalogued as rs775010884, COSV56887003; called by muse, mutect2, varscan2
- GRIP1 | c.2237C>A p.T746N (on ENST00000359742 / NM_001379345.1; = p.T694N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/175 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV54019617; called by muse, mutect2, varscan2
- GRM3 | c.762G>T p.K254N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as COSV64469417; called by muse, mutect2, varscan2
- HDAC9 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV67770387; called by muse, mutect2
- HEPACAM2 | c.515T>C p.V172A (on ENST00000394468 / NM_001039372.4; = p.V160A on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV100506843, COSV59059203; called by muse, mutect2, varscan2
- HEPH | c.1418A>G p.Y473C (on ENST00000343002; = p.Y206C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); catalogued as COSV57961271; called by muse, mutect2, varscan2
- HSPG2 | c.10262G>C p.C3421S | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65932949; called by muse, mutect2
- IL20RB | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs775235617, COSV59047229; called by muse, mutect2, varscan2
- ITGB3BP | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV52131666; called by muse, mutect2, varscan2
- KANK2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs766622487, COSV62007317; called by muse, mutect2, varscan2
- KCNA10 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV63904442; called by muse, mutect2, varscan2
- KCNA10 | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs750444854, COSV63904445, COSV63905448; called by muse, mutect2, varscan2
- KIAA1109 | c.10092G>C p.L3364F | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52667172; called by muse, mutect2, varscan2
- KIF5A | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs774586838, COSV54052942; called by muse, mutect2, varscan2
- KIRREL2 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52875185; called by muse, mutect2, varscan2
- LRRC8B | c.1393C>T p.L465F | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1425549802, COSV58374140, COSV58375629; called by muse, mutect2, varscan2
- LRRK1 | c.2989T>G p.S997A | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52606383; called by muse, mutect2, varscan2
- LRRTM4 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV69139539; called by muse, mutect2, varscan2
- MAGEE1 | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs782456206, COSV63909399; called by muse, mutect2, varscan2
- MAGEE2 | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.51); catalogued as COSV64897511; called by muse, mutect2, varscan2
- MAGEE2 | c.1134C>A p.Y378* | Nonsense Mutation (SNP) | VAF 84/177 reads (47%) | catalogued as COSV64897515; called by muse, mutect2, varscan2
- MROH2B | c.3374T>A p.L1125Q | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68182610; called by muse, mutect2, varscan2
- MRTFA | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 132/232 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1438330076, COSV62932378; called by muse, mutect2, varscan2
- MUC16 | c.41113G>A p.A13705T | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.961); catalogued as COSV66690895; called by muse, mutect2, varscan2
- MYBL1 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as rs773502075, COSV72918866; called by muse, mutect2, varscan2
- NIBAN3 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.103); catalogued as COSV56306942; called by muse, mutect2, varscan2
- NLGN3 | c.988T>G p.Y330D (on ENST00000358741 / NM_181303.2; = p.Y310D on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV62442282; called by muse, mutect2, varscan2
- NLRP5 | c.1889C>A p.S630* | Nonsense Mutation (SNP) | VAF 54/98 reads (55%) | catalogued as COSV66763304; called by muse, mutect2, varscan2
- OR51S1 | c.556T>A p.Y186N | Missense Mutation (SNP) | VAF 92/138 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59057912; called by muse, mutect2, varscan2
- OR8B3 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 84/157 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1372272364, COSV63541513; called by muse, mutect2, varscan2
- OSER1 | c.166del p.C56Vfs*19 | Frame Shift Del (DEL) | VAF 34/102 reads (33%) | catalogued as COSV54854676; called by mutect2, pindel, varscan2
- OSMR | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV57083226; called by muse, mutect2, varscan2
- P3H2 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs780112859, COSV60020039; called by muse, mutect2
- PAX5 | c.1063A>T p.N355Y | Missense Mutation (SNP) | VAF 94/152 reads (62%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV63906252, COSV63914487; called by muse, mutect2, varscan2
- PCDH1 | c.2643G>T p.E881D | Missense Mutation (SNP) | VAF 219/330 reads (66%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV54612639; called by muse, mutect2, varscan2
- PCDH7 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62337718, COSV62340917; called by muse, mutect2, varscan2
- PCDHA7 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 100/149 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV65342100, COSV65343224; called by muse, mutect2, varscan2
- PDE3A | c.2926-1G>T p.X976_splice | Splice Site (SNP) | VAF 45/122 reads (37%) | catalogued as COSV100761486, COSV62970454; called by muse, mutect2, varscan2
- PDGFRA | c.1164C>A p.D388E | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.771); catalogued as COSV57266673; called by muse, mutect2, varscan2
- PHF8 | c.1354C>T p.H452Y (on ENST00000357988 / NM_001184896.1; = p.H416Y on NM_015107.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57679336; called by muse, mutect2
- PLA1A | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV56331116; called by muse, mutect2, varscan2
- PLPPR4 | c.407C>G p.T136R | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV64568768; called by muse, mutect2, varscan2
- PPFIBP1 | c.1043-1G>T p.X348_splice (on ENST00000318304 / NM_177444.3; = p.X331_splice on NM_003622.4) | Splice Site (SNP) | VAF 42/84 reads (50%) | catalogued as COSV57289531; called by muse, mutect2, varscan2
- PPFIBP2 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.997); catalogued as COSV55075735; called by muse, mutect2, varscan2
- PROS1 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV62398137; called by muse, mutect2, varscan2
- PSTK | c.929C>A p.A310E | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.382); catalogued as COSV100924749, COSV64397381; called by muse, varscan2
- PZP | c.3710C>A p.A1237E | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779184815, COSV54357354, COSV99062411; called by muse, mutect2, varscan2
- RNF113A | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 88/373 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65097215; called by muse, mutect2, varscan2
- SEMG2 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as COSV65647320; called by muse, mutect2, varscan2
- SHC4 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs776839877, COSV60110778; called by muse, mutect2, varscan2
- SHC4 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100195439; called by muse, mutect2, varscan2
- SLITRK2 | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 183/378 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV59424166; called by muse, mutect2, varscan2
- SMARCA1 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 128/212 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64411412; called by muse, mutect2, varscan2
- SPOCD1 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs778359963, COSV57095268; called by muse, mutect2, varscan2
- SPTA1 | c.648A>C p.E216D | Missense Mutation (SNP) | VAF 89/165 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV104426753, COSV63751055; called by muse, varscan2
- SPTA1 | c.622G>T p.V208L | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV63751058; called by muse, varscan2
- SRD5A3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV51711585; called by muse, mutect2, varscan2
- STK26 | c.148G>A p.V50I | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs777377443, COSV61229236; called by muse, mutect2, varscan2
- SVEP1 | c.5800G>T p.G1934* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV52837591; called by muse, mutect2, varscan2
- SYTL5 | c.1842-1G>T p.X614_splice | Splice Site (SNP) | VAF 27/54 reads (50%) | catalogued as COSV52899696; called by muse, mutect2, varscan2
- TBC1D31 | c.2929G>T p.E977* | Nonsense Mutation (SNP) | VAF 51/85 reads (60%) | catalogued as COSV54864942; called by muse, mutect2, varscan2
- TBL2 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.221); catalogued as COSV59786556; called by muse, mutect2, varscan2
- TENM1 | c.4396G>T p.G1466C | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64428595; called by muse, mutect2, varscan2
- TG | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV55070778; called by muse, mutect2
- TIMM17B | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54429823; called by muse, mutect2, varscan2
- TMCC1 | c.101T>C p.L34S | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV67872682; called by muse, mutect2, varscan2
- TRAK2 | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV60271087, COSV60271345; called by muse, mutect2, varscan2
- TRIOBP | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 148/528 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV60375541; called by muse, mutect2, varscan2
- TRPC7 | c.1661G>T p.R554L | Missense Mutation (SNP) | VAF 75/109 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs183404828, COSV61456054; called by muse, mutect2, varscan2
- TSHZ2 | c.2572G>T p.A858S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100296040, COSV61587826; called by muse, mutect2, varscan2
- TTN | c.36338G>A p.G12113D (on ENST00000591111; = p.G4689D on NM_003319.4) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV59964653; called by muse, mutect2, varscan2
- UGT3A2 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV56929413; called by muse, mutect2, varscan2
- USH1C | c.1632G>T p.E544D | Missense Mutation (SNP) | VAF 52/80 reads (65%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV50014958; called by muse, mutect2, varscan2
- USH2A | c.605C>A p.T202K | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56349314; called by muse, mutect2, varscan2
- USP24 | c.6704G>A p.R2235Q | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs764984366, COSV53765126; called by muse, mutect2, varscan2
- WDR45 | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV59875756; called by muse, varscan2
- WDR90 | c.4004T>C p.L1335S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV53467985; called by muse, mutect2, varscan2
- ZCCHC13 | c.497A>T p.Q166L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59866105; called by muse, mutect2, varscan2
- ZNF407 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV55247802; called by muse, mutect2, varscan2
- ZNF48 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.118); catalogued as rs144019727; called by muse, mutect2, varscan2
- ZNF676 | c.386G>T p.G129V (on ENST00000650058; = p.G97V on NM_001001411.3) | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.556); catalogued as rs1490339390, COSV68092658; called by muse, mutect2, varscan2
- ZNF746 | c.1098G>C p.E366D | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs778694770, COSV61406921; called by muse, mutect2, varscan2
- ZNF804B | c.2411G>T p.C804F | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV60822241; called by muse, mutect2, varscan2
- ABCB7 | c.890C>A p.T297N (on ENST00000373394 / NM_001271696.3; = p.T298N on NM_004299.6) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- C16orf82 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DSP | c.4705_4720del p.Q1569Kfs*4 | Frame Shift Del (DEL) | VAF 52/80 reads (65%) | called by mutect2, pindel, varscan2
- HRH3 | c.89C>A p.S30* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- KNL1 | c.1301del p.I434Nfs*2 (on ENST00000346991 / NM_170589.5; = p.I408Nfs*2 on NM_144508.5) | Frame Shift Del (DEL) | VAF 31/296 reads (10%) | called by mutect2, pindel, varscan2
- PCDHA11 | c.1341del p.N448Tfs*16 | Frame Shift Del (DEL) | VAF 113/204 reads (55%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.2409_2413del p.W804Vfs*5 | Frame Shift Del (DEL) | VAF 57/103 reads (55%) | called by mutect2, pindel, varscan2
- ADGRF1 | c.2016C>T p.F672= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as rs745392518, COSV51944510, COSV99347125; called by muse, mutect2, varscan2
- BEND3 | c.678C>T p.R226= | Silent (SNP) | VAF 50/75 reads (67%) | catalogued as rs1360485514, COSV64680654; called by muse, mutect2, varscan2
- BIRC6 | c.10494A>G p.A3498= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as COSV70197376; called by muse, mutect2, varscan2
- CCNB3 | c.2064C>A p.S688= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV52071677; called by muse, mutect2, varscan2
- CD1A | c.318G>A p.Q106= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV56861031; called by muse, mutect2, varscan2
- CD300LB | c.123A>T p.G41= | Silent (SNP) | VAF 298/525 reads (57%) | catalogued as COSV58725413; called by muse, mutect2, varscan2
- CHM | c.408T>C p.S136= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV63301050; called by muse, mutect2, varscan2
- COL17A1 | c.588G>C p.V196= | Silent (SNP) | VAF 47/70 reads (67%) | catalogued as COSV62226100; called by muse, mutect2, varscan2
- COL9A1 | c.1422C>A p.T474= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as rs540419799, COSV57881547, COSV57892084; called by muse, varscan2
- COPZ1 | c.417C>A p.P139= | Silent (SNP) | VAF 68/151 reads (45%) | catalogued as COSV50432145; called by muse, mutect2, varscan2
- CSMD1 | c.174C>T p.C58= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as rs750265179, COSV68186250; called by muse, mutect2, varscan2
- CYB561 | c.285C>T p.L95= | Silent (SNP) | VAF 80/97 reads (82%) | catalogued as rs372231804, COSV100669117, COSV62539572; called by muse, mutect2, varscan2
- DCC | c.1296C>A p.P432= | Silent (SNP) | VAF 139/210 reads (66%) | catalogued as COSV59094242; called by muse, mutect2, varscan2
- DOK5 | c.234T>C p.H78= | Silent (SNP) | VAF 12/313 reads (4%) | catalogued as COSV52818441; called by muse, mutect2
- EPHB1 | c.687A>G p.A229= | Silent (SNP) | VAF 409/640 reads (64%) | catalogued as COSV67657264; called by muse, mutect2, varscan2
- FAM214B | c.1278C>A p.T426= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV59715472; called by muse, mutect2, varscan2
- FOXI1 | c.531C>T p.L177= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV60388348; called by muse, mutect2, varscan2
- GABRG1 | c.66G>A p.R22= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV54951806; called by muse, mutect2, varscan2
- GPR82 | c.177T>C p.T59= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV56886986; called by muse, mutect2, varscan2
- INO80D | c.2445A>G p.Q815= | Silent (SNP) | VAF 72/366 reads (20%) | catalogued as rs776016929, COSV68958487; called by muse, varscan2
- KIAA1755 | c.2148C>A p.T716= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV54075018, COSV54079674; called by muse, mutect2, varscan2
- LARGE1 | c.237C>T p.L79= | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as rs1442851403, COSV61659853; called by muse, mutect2, varscan2
- LCT | c.1803G>A p.L601= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV51546528; called by muse, mutect2, varscan2
- MME | c.573G>A p.L191= | Silent (SNP) | VAF 168/267 reads (63%) | catalogued as rs984925438, COSV64706609; called by muse, mutect2, varscan2
- MMP19 | c.819C>A p.P273= | Silent (SNP) | VAF 60/93 reads (65%) | catalogued as rs1177236949, COSV59450899; called by muse, mutect2, varscan2
- MOCS1 | c.1866C>G p.L622= | Silent (SNP) | VAF 113/179 reads (63%) | catalogued as COSV51306841; called by muse, mutect2, varscan2
- MUC16 | c.25254G>A p.L8418= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as rs753600464, COSV67455937, COSV67490209; called by muse, mutect2, varscan2
- NEUROD6 | c.834C>A p.T278= | Silent (SNP) | VAF 69/137 reads (50%) | catalogued as rs1411145439, COSV51770796; called by muse, mutect2, varscan2
- NIBAN1 | c.2028C>T p.L676= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs376073509, COSV62286409; called by muse, mutect2, varscan2
- NTM | c.699C>A p.V233= | Silent (SNP) | VAF 108/171 reads (63%) | catalogued as rs936241367, COSV66176495; called by muse, mutect2, varscan2
- NTRK3 | c.2073G>A p.L691= | Silent (SNP) | VAF 110/179 reads (61%) | catalogued as COSV62299796; called by muse, mutect2, varscan2
- OR14A16 | c.852C>G p.P284= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV62926364, COSV62926753, COSV62927279; called by muse, mutect2, varscan2
- OR4A15 | c.885C>A p.A295= | Silent (SNP) | VAF 80/150 reads (53%) | catalogued as COSV59034307; called by muse, mutect2, varscan2
- P2RY10 | c.978C>T p.S326= | Silent (SNP) | VAF 110/239 reads (46%) | catalogued as COSV50680735, COSV99409372; called by muse, mutect2, varscan2
- PPP1R3F | c.2361G>T p.L787= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV50017952; called by muse, mutect2, varscan2
- SATB2 | c.1263C>T p.F421= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV53480782; called by muse, mutect2, varscan2
- SENP5 | c.1113G>A p.L371= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as COSV60205962; called by muse, mutect2
- SFMBT2 | c.264G>A p.P88= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as rs772130509, COSV62807407; called by muse, mutect2, varscan2
- SIPA1L3 | c.1959C>T p.F653= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV55911422; called by muse, mutect2, varscan2
- STEAP3 | c.1116C>T p.S372= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV61528452; called by muse, mutect2, varscan2
- TERT | c.3318G>A p.K1106= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV57207553; called by muse, mutect2, varscan2
- TLR7 | c.2586C>G p.L862= | Silent (SNP) | VAF 71/347 reads (20%) | catalogued as COSV66123901; called by muse, mutect2, varscan2
- TRIM38 | c.1314G>T p.P438= | Silent (SNP) | VAF 62/105 reads (59%) | catalogued as rs1273319550, COSV62641977; called by muse, mutect2, varscan2
- TRRAP | c.4707A>G p.T1569= (on ENST00000359863 / NM_001244580.1; = p.T1551= on NM_003496.3) | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as rs531306029, COSV62841879; called by muse, mutect2, varscan2
- TTLL12 | c.1803G>A p.P601= | Silent (SNP) | VAF 61/157 reads (39%) | catalogued as rs142420296, COSV53354708; called by muse, mutect2, varscan2
- USH2A | c.606A>C p.T202= | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as COSV56349289; called by muse, mutect2, varscan2
- USP24 | c.2994G>T p.V998= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV53765142; called by muse, mutect2
- WWC3 | c.2238C>A p.S746= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV66504699; called by muse, mutect2, varscan2
- ZDBF2 | c.3000A>C p.T1000= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV65623625; called by muse, mutect2, varscan2
- ZNF439 | c.723G>A p.P241= | Silent (SNP) | VAF 102/216 reads (47%) | catalogued as rs370512382; called by muse, mutect2, varscan2
- ZNF676 | c.1257T>C p.H419= (on ENST00000650058; = p.H387= on NM_001001411.3) | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as COSV68092654; called by muse, mutect2, varscan2
- ZNF708 | c.1131A>T p.S377= | Silent (SNP) | VAF 46/161 reads (29%) | catalogued as COSV63607170; called by muse, mutect2, varscan2
- GCNT2 | c.926-35103C>G | Intron (SNP) | VAF 20/96 reads (21%) | catalogued as rs11966400; called by muse, mutect2, varscan2
- MIR1-1 | n.68C>T | RNA (SNP) | VAF 70/198 reads (35%) | called by muse, mutect2, varscan2
- MIR517C | n.35A>C | RNA (SNP) | VAF 26/86 reads (30%) | called by muse, varscan2
- MIR517C | n.64A>T | RNA (SNP) | VAF 24/62 reads (39%) | called by muse, varscan2
- TTN | c.34265-3035C>G | Intron (SNP) | VAF 32/82 reads (39%) | catalogued as COSV59964692; called by muse, mutect2, varscan2
